Somatic mutation profile of tumor specimen BA2065D (aliquot aq-BA2065D) from BEATAML1.0 case 2029, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.4 years (16,941 days).
Specimen BA2065D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d5b71b4-db3b-449d-b4f1-4eaf10d59842.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2368D (Solid Tissue Normal), aliquot aq-BA2368D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05324be9-4d7e-4757-81da-e86bdf67b0d9

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOP1B | c.4178C>A p.A1393E | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101214885; called by muse, mutect2
- GRM4 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as rs201918690, COSV65216725; called by muse, mutect2, varscan2
- H1-2 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV59190538; called by muse, mutect2
- INPP4A | c.2486G>A p.R829Q (on ENST00000074304 / NM_001134224.1; = p.R790Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs775014766, COSV50790352, COSV50801650; called by muse, mutect2, varscan2
- KANSL2 | c.1013G>T p.C338F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100770970; called by muse, mutect2
- CCN5 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- KIAA1109 | c.14103C>A p.G4701= | Splice Region (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- MUC16 | c.43178G>T p.C14393F | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TC2N | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- LHPP | c.660C>T p.V220= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs748176426; called by muse, varscan2
- POLD3 | c.1302A>G p.K434= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- RAI1 | c.3867C>A p.A1289= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- RHBDF2 | c.1617G>T p.L539= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- AC009126.1 | n.2019A>C | RNA (SNP) | VAF 10/84 reads (12%) | called by mutect2, varscan2
